Somatic mutation profile of tumor specimen TCGA-QK-A8Z8-01A (aliquot TCGA-QK-A8Z8-01A-11D-A391-08) from TCGA case TCGA-QK-A8Z8, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: G2; Age at diagnosis: 60.5 years (22,107 days).
Specimen TCGA-QK-A8Z8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40352a10-7ac5-4052-b5d9-cba325275ee1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A8Z8-10A (Blood Derived Normal), aliquot TCGA-QK-A8Z8-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3b8ca99-0423-4fba-8395-390af85026d7

The open-access MAF lists 433 somatic variants for this specimen: 319 protein-altering or splice-affecting, 103 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 103, Nonsense Mutation 27, Frame Shift Del 17, RNA 6, Frame Shift Ins 5, Splice Region 5, Splice Site 4, Intron 3, Nonstop Mutation 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 67/97 reads (69%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); catalogued as rs193922218, COSV100356055; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 39/70 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.573C>T p.I191= | Splice Region (SNP) | VAF 51/88 reads (58%) | catalogued as rs762904487, COSV99286565; called by muse, mutect2, varscan2
- ACE2 | c.1418G>T p.W473L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV99383030; called by muse, mutect2, varscan2
- ACMSD | c.69C>G p.Y23* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as COSV99299367; called by muse, mutect2, varscan2
- ACTL7A | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.733); catalogued as rs753369277, COSV61776714; called by muse, mutect2, varscan2
- ADAMTS14 | c.3188G>T p.C1063F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941781; called by muse, mutect2, varscan2
- AEBP1 | c.2073G>T p.W691C | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1343912630, COSV99789007; called by muse, mutect2, varscan2
- AKAP17A | c.1951A>T p.S651C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV100002409; called by muse, mutect2, varscan2
- ALPP | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101235177; called by muse, mutect2, varscan2
- AMBRA1 | c.2408G>A p.R803H (on ENST00000458649 / NM_001367468.1; = p.R713H on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100094943; called by muse, varscan2
- AMY2B | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs554748949, COSV100796444; called by muse, mutect2, varscan2
- ANGEL1 | c.1844A>G p.N615S | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV99200461; called by muse, mutect2, varscan2
- ANK2 | c.10319C>G p.S3440C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100003378, COSV52167575; called by muse, mutect2, varscan2
- APOB | c.2990G>C p.G997A | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99267174; called by muse, mutect2, varscan2
- ARAF | c.619del p.L207Yfs*85 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as COSV51695741; called by mutect2, pindel, varscan2
- ARFGEF1 | c.3518C>T p.S1173L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51603747; called by muse, mutect2, varscan2
- ARHGAP4 | c.1275G>T p.Q425H | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV100604178; called by muse, mutect2, varscan2
- ASAP1 | c.989A>T p.Y330F | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.043); catalogued as COSV100727657; called by muse, mutect2, varscan2
- ASH1L | c.8171G>C p.R2724P (on ENST00000368346 / NM_001366177.2; = p.R2719P on NM_018489.3) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100853555; called by muse, mutect2, varscan2
- ASPM | c.6338T>A p.I2113N | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as CD091972, COSV99660894; called by muse, mutect2, varscan2
- ATP1A3 | c.778G>T p.V260L (on ENST00000545399 / NM_001256214.2; = p.V247L on NM_152296.5) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100132467; called by muse, mutect2, varscan2
- ATXN2L | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100294922; called by muse, mutect2, varscan2
- BTBD3 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs530038210, COSV54779203; called by muse, mutect2, varscan2
- BTN1A1 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99764507; called by muse, mutect2, varscan2
- CAMTA1 | c.447C>A p.Y149* | Nonsense Mutation (SNP) | VAF 51/165 reads (31%) | catalogued as COSV100351871, COSV57928378; called by muse, mutect2, varscan2
- CCDC171 | c.3821G>T p.G1274V | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV101048552; called by muse, mutect2, varscan2
- CD163L1 | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV100550531; called by muse, mutect2, varscan2
- CD207 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101338585; called by muse, mutect2, varscan2
- CDC5L | c.1772C>G p.P591R | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs61753598; called by muse, mutect2, varscan2
- CDH11 | c.1303C>A p.P435T | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV99219400; called by muse, mutect2, varscan2
- CDH15 | c.2079G>T p.Q693H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99228712; called by muse, mutect2, varscan2
- CEACAM20 | c.1614G>A p.T538= | Splice Region (SNP) | VAF 32/71 reads (45%) | catalogued as rs762179860, COSV57601271; called by muse, mutect2, varscan2
- CEP250 | c.7277G>T p.G2426V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as COSV100699097; called by muse, mutect2, varscan2
- CHST13 | c.404C>G p.P135R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100081319; called by muse, mutect2, varscan2
- CHST13 | c.1024T>A p.*342Kext*222 | Nonstop Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100081322; called by muse, mutect2
- CHST2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1160891339, COSV100536060; called by muse, mutect2, varscan2
- CLEC1A | c.801G>C p.E267D | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV100191645; called by muse, mutect2, varscan2
- CMYA5 | c.6836A>C p.K2279T | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as rs1449589887, COSV101484270; called by muse, mutect2, varscan2
- CNOT2 | c.502A>G p.R168G | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.528); catalogued as COSV99972955; called by muse, mutect2, varscan2
- CNTN2 | c.1219A>T p.S407C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV59353166; called by muse, mutect2, varscan2
- COL6A6 | c.4511C>A p.A1504E | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100650736; called by muse, mutect2, varscan2
- CPQ | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.677); catalogued as COSV99613907; called by muse, mutect2, varscan2
- CRB1 | c.1207T>C p.S403P | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV100958036; called by muse, mutect2, varscan2
- CREG1 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100981914; called by muse, mutect2, varscan2
- CSMD3 | c.10063C>A p.P3355T (on ENST00000297405 / NM_001363185.1; = p.P3186T on NM_052900.3) | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843291; called by muse, mutect2, varscan2
- CSMD3 | c.7020G>C p.W2340C (on ENST00000297405 / NM_001363185.1; = p.W2236C on NM_052900.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372658569; called by muse, mutect2, varscan2
- CST1 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100494376; called by muse, mutect2, varscan2
- CTNNA2 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764567856, COSV63605433, COSV63612163; called by muse, mutect2, varscan2
- CTNNA2 | c.1718C>G p.A573G | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as COSV100561677; called by muse, mutect2, varscan2
- CTNNA3 | c.460-1G>T p.X154_splice | Splice Site (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100373727; called by muse, mutect2, varscan2
- CTNND2 | c.2730C>A p.C910* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | catalogued as COSV100479720, COSV58872802; called by muse, mutect2, varscan2
- CUL4B | c.2177C>G p.T726S | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV100341018; called by muse, mutect2, varscan2
- CYB561 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); catalogued as COSV100669152; called by muse, varscan2
- DBX2 | c.899A>G p.E300G | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.628); catalogued as COSV100224446, COSV60336099; called by muse, mutect2, varscan2
- DCAF15 | c.168G>C p.K56N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99586906; called by muse, mutect2, varscan2
- DDO | c.911A>G p.Y304C (on ENST00000368924 / NM_001368172.1; = p.Y245C on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927889; called by muse, mutect2, varscan2
- DDX60L | c.4381C>T p.Q1461* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99488122; called by muse, mutect2
- DEFB118 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV53620718, COSV99489301; called by muse, mutect2, varscan2
- DENND5B | c.3383T>C p.V1128A | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100171977; called by muse, mutect2, varscan2
- DLG3 | c.1031T>G p.L344R | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV99529930; called by muse, mutect2, varscan2
- DMD | c.6064G>T p.D2022Y | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100821900; called by muse, mutect2, varscan2
- DMD | c.3454T>A p.L1152M | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100821901; called by muse, mutect2, varscan2
- DMD | c.484A>T p.S162C | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as CD160934, COSV99924932; called by muse, mutect2, varscan2
- DMKN | c.298G>T p.G100W | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100303871; called by muse, mutect2, varscan2
- DNAH10 | c.8463G>A p.Q2821= (on ENST00000409039; = p.Q2760= on NM_207437.3) | Splice Region (SNP) | VAF 56/224 reads (25%) | catalogued as COSV101292490; called by muse, mutect2, varscan2
- DNAH5 | c.6121G>T p.V2041F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99452607; called by muse, mutect2, varscan2
- DNAH5 | c.2259G>T p.K753N | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV99452609; called by muse, mutect2, varscan2
- DNAH8 | c.11859G>T p.Q3953H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV100544729, COSV100546686; called by muse, mutect2, varscan2
- DNAI4 | c.1034G>T p.S345I | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV100925308; called by muse, mutect2, varscan2
- DNAJC11 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 80/266 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs372201952, COSV99602497; called by muse, mutect2, varscan2
- DSCAML1 | c.6214C>T p.R2072* (on ENST00000321322; = p.R2012* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 30/46 reads (65%) | catalogued as COSV58385753; called by muse, mutect2, varscan2
- DSP | c.2697C>A p.C899* | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | catalogued as COSV101131614; called by muse, mutect2, varscan2
- DTL | c.1999G>T p.A667S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV100877251, COSV100877254; called by muse, mutect2, varscan2
- EDIL3 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56904239; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1009G>T p.A337S (on ENST00000361735 / NM_015935.5; = p.A251S on NM_014955.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV100675984; called by muse, mutect2, varscan2
- EPHA5 | c.1028T>C p.F343S | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.205); catalogued as COSV99900473; called by muse, mutect2, varscan2
- ERBB4 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.983); catalogued as COSV99629886; called by muse, mutect2, varscan2
- ERV3-1 | c.994A>T p.S332C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV99275978; called by muse, mutect2, varscan2
- EVPL | c.4526T>A p.L1509H | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101440960; called by muse, mutect2, varscan2
- EXO1 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100800088, COSV62220780; called by muse, varscan2
- EYA1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as CM000144, COSV100380059; called by muse, mutect2, varscan2
- EZHIP | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.842); catalogued as rs1557318628, COSV57955675; called by muse, mutect2, varscan2
- FAM114A1 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.403); catalogued as COSV100729438; called by muse, mutect2, varscan2
- FAM174B | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV59264351; called by muse, mutect2, varscan2
- FAM47C | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100792877; called by muse, mutect2, varscan2
- FAM71F1 | c.209T>A p.L70Q | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100171101; called by muse, mutect2, varscan2
- FAM83E | c.100G>C p.A34P | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99320353; called by muse, varscan2
- FAM98C | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.962); catalogued as COSV99385107; called by muse, mutect2
- FBN1 | c.2188G>T p.D730Y | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as CM145707, COSV100356052; called by muse, mutect2, varscan2
- FBN2 | c.8303A>G p.N2768S | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99329793; called by muse, mutect2, varscan2
- FER1L6 | c.5289+1G>C p.X1763_splice | Splice Site (SNP) | VAF 28/104 reads (27%) | catalogued as COSV101206113; called by muse, mutect2, varscan2
- FLG | c.8384G>T p.G2795V | Missense Mutation (SNP) | VAF 102/638 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.307); catalogued as COSV64242807; called by muse, mutect2, varscan2
- FLG | c.8383G>A p.G2795R | Missense Mutation (SNP) | VAF 105/638 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs779385755, COSV64241727; called by muse, mutect2, varscan2
- FLNA | c.6302C>T p.T2101M (on ENST00000369850 / NM_001110556.2; = p.T2093M on NM_001456.3) | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1289908513, COSV100775010; called by muse, mutect2, varscan2
- FLNC | c.4865C>T p.P1622L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100368555; called by muse, mutect2, varscan2
- FLNC | c.5404G>T p.V1802L | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV100368556, COSV100368601; called by muse, mutect2, varscan2
- FMO1 | c.39C>G p.S13R | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100707883; called by muse, mutect2, varscan2
- FNDC4 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV99254004; called by muse, mutect2, varscan2
- FOXO1 | c.1582G>T p.A528S | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101092105; called by muse, mutect2, varscan2
- FPGT | c.1616G>T p.R539L | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs756604825, COSV100907472, COSV63838375; called by muse, mutect2, varscan2
- FREM2 | c.6647G>C p.R2216P | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99750119; called by muse, mutect2, varscan2
- FXYD1 | c.93C>T p.Y31= | Splice Region (SNP) | VAF 25/87 reads (29%) | catalogued as rs746736667, COSV99544989; called by muse, mutect2, varscan2
- FZD6 | c.1210G>T p.G404C | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100708465; called by muse, mutect2, varscan2
- GABRE | c.220A>T p.I74F | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100944338; called by muse, mutect2, varscan2
- GABRG1 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); catalogued as COSV99778527; called by muse, mutect2, varscan2
- GC | c.619A>T p.K207* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99910024; called by muse, mutect2, varscan2
- GCNT4 | c.409T>A p.L137M | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.453); catalogued as COSV100466556; called by muse, mutect2, varscan2
- GDPD3 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV99531882; called by muse, mutect2, varscan2
- GEMIN4 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100021551; called by muse, mutect2, varscan2
- GHR | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100050510; called by muse, mutect2, varscan2
- GNL3L | c.189G>T p.W63C | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV100328548; called by muse, mutect2
- GNL3L | c.1176G>T p.W392C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100328551; called by muse, mutect2, varscan2
- GRM1 | c.702G>T p.G234= | Splice Region (SNP) | VAF 27/99 reads (27%) | catalogued as COSV99268235, COSV99269019; called by muse, mutect2, varscan2
- HMGCR | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV99843331, COSV99843415; called by muse, mutect2, varscan2
- HPS4 | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV100404605; called by muse, mutect2, varscan2
- HSH2D | c.119C>A p.S40* | Nonsense Mutation (SNP) | VAF 61/125 reads (49%) | catalogued as COSV99507383; called by muse, mutect2, varscan2
- IGKV1-12 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as rs766103271; called by muse, mutect2, varscan2
- IKZF1 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 73/86 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100498631, COSV58784478; called by muse, mutect2, varscan2
- IL22 | c.37A>C p.M13L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100048917; called by muse, mutect2, varscan2
- IMPG2 | c.678A>T p.E226D | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV99516180; called by muse, mutect2, varscan2
- IQCG | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99502595; called by muse, mutect2, varscan2
- ITGA4 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99276681; called by muse, mutect2, varscan2
- ITGAL | c.2146-1G>A p.X716_splice | Splice Site (SNP) | VAF 36/84 reads (43%) | catalogued as COSV100776320; called by muse, mutect2, varscan2
- ITPKC | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99648998; called by muse, mutect2
- IVNS1ABP | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.088); catalogued as COSV100832558, COSV62250185; called by muse, mutect2, varscan2
- JAG1 | c.1495G>T p.G499W | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as CD972286, COSV99653330; called by muse, mutect2, varscan2
- KBTBD3 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV101595714; called by muse, mutect2
- KCNU1 | c.1011T>A p.C337* | Nonsense Mutation (SNP) | VAF 34/65 reads (52%) | catalogued as COSV101299392; called by muse, mutect2, varscan2
- KCTD8 | c.457C>G p.Q153E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV100759924; called by muse, mutect2, varscan2
- KDELR1 | c.395T>C p.L132S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100416521; called by muse, mutect2, varscan2
- KDR | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.174); catalogued as COSV99818378; called by muse, mutect2, varscan2
- KIF16B | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV100734762; called by muse, mutect2, varscan2
- KIF26A | c.1886G>T p.R629L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100181469; called by muse, mutect2, varscan2
- KIT | c.2663G>T p.R888L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55391670, COSV99855011; called by muse, mutect2, varscan2
- KLC1 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99871762; called by muse, mutect2, varscan2
- KLF7 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.926); catalogued as rs1231413667, COSV58743962; called by muse, mutect2, varscan2
- KLHL11 | c.1229A>T p.Y410F | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as COSV100044445, COSV59863271; called by muse, mutect2, varscan2
- KLHL34 | c.1579G>T p.A527S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs1397081875, COSV101069977; called by muse, mutect2, varscan2
- KLK15 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100032913; called by muse, mutect2, varscan2
- LAMP2 | c.993C>A p.C331* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV52352295; called by muse, mutect2, varscan2
- LANCL3 | c.1079C>A p.S360Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.905); catalogued as COSV101065726; called by muse, mutect2, varscan2
- LASP1 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.049); catalogued as COSV100530434; called by muse, mutect2, varscan2
- LHX9 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100436018; called by muse, mutect2, varscan2
- LMTK3 | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99541020; called by muse, mutect2, varscan2
- LRR1 | c.211A>T p.T71S | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV100023247; called by muse, mutect2, varscan2
- LRRTM4 | c.1445A>T p.Q482L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101297678; called by muse, mutect2, varscan2
- MAGEB6 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100983824, COSV99081183; called by muse, mutect2, varscan2
- MAGEC1 | c.35C>A p.P12Q | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); catalogued as COSV99596235; called by muse, mutect2, varscan2
- MAGEC1 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as rs748272878, COSV99596237; called by muse, mutect2, varscan2
- MAGEC1 | c.502A>T p.S168C | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV99595960, COSV99596238; called by muse, varscan2
- MCF2 | c.1933C>A p.L645I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100645003; called by muse, mutect2, varscan2
- MDN1 | c.5258G>T p.G1753V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101021670; called by muse, mutect2, varscan2
- MGAT4A | c.1096T>A p.S366T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99384595; called by muse, mutect2, varscan2
- MS4A1 | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV100619407; called by muse, mutect2, varscan2
- MUC16 | c.41615G>T p.G13872V | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.996); catalogued as COSV101110019; called by muse, mutect2, varscan2
- MUC21 | c.266C>G p.T89R | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1380243219, COSV100888907; called by muse, varscan2
- NAALADL2 | c.316T>A p.Y106N | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV101435787; called by muse, mutect2, varscan2
- NCAM2 | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1438881603, COSV53070620, COSV53085581; called by muse, mutect2, varscan2
- NCAPD2 | c.3653+1G>T p.X1218_splice | Splice Site (SNP) | VAF 23/90 reads (26%) | catalogued as COSV99975631; called by muse, mutect2, varscan2
- NDST1 | c.2209G>C p.G737R | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as COSV99939023; called by muse, mutect2, varscan2
- NDST1 | c.2210G>T p.G737V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV55789132; called by muse, mutect2, varscan2
- NHS | c.1329C>G p.I443M | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101196885; called by muse, mutect2, varscan2
- NKX2-2 | c.204C>A p.S68R | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs202157567, COSV65820557; called by muse, mutect2, varscan2
- NLGN3 | c.1247G>A p.G416E (on ENST00000358741 / NM_181303.2; = p.G396E on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV100704972; called by muse, mutect2, varscan2
- NLRP3 | c.2329C>G p.R777G | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV100276465, COSV60228880; called by muse, varscan2
- NR1H2 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53800233, COSV99516486; called by muse, mutect2, varscan2
- NR3C2 | c.1972T>G p.C658G | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100679601; called by muse, mutect2, varscan2
- NRG3 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV64545488, COSV64554143; called by muse, mutect2, varscan2
- NRXN1 | c.656C>A p.A219E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1360707101, COSV101279035, COSV68013853; called by muse, mutect2
- NSA2 | c.17A>C p.Y6S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV57187510; called by muse, mutect2, varscan2
- NSD1 | c.5618_5619del p.I1873Kfs*18 | Frame Shift Del (DEL) | VAF 30/60 reads (50%) | catalogued as rs587784152; called by pindel, varscan2
- NUDT10 | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100726838; called by muse, mutect2, varscan2
- NUDT12 | c.1085C>A p.T362K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100048298; called by muse, mutect2, varscan2
- NVL | c.2029G>T p.V677L | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99894910; called by muse, mutect2, varscan2
- NXPE3 | c.1324A>G p.I442V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs1378278868, COSV99840099; called by muse, mutect2, varscan2
- OFD1 | c.1380G>C p.E460D | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.056); catalogued as COSV100407062; called by muse, mutect2, varscan2
- OR10A7 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100406621; called by muse, mutect2, varscan2
- OR13C8 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100623003; called by muse, mutect2, varscan2
- OR1J4 | c.355G>C p.A119P | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100534305; called by muse, mutect2, varscan2
- OR5AC2 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 102/236 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100684452; called by muse, mutect2, varscan2
- OR5H14 | c.532T>G p.Y178D | Missense Mutation (SNP) | VAF 94/186 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101454240, COSV71193438; called by muse, mutect2, varscan2
- OR6F1 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100128947, COSV100129380; called by muse, mutect2, varscan2
- OTOGL | c.7037T>G p.I2346R (on ENST00000547103; = p.I2337R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV100087687; called by muse, mutect2
- PAPPA2 | c.4219G>C p.V1407L | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.024); catalogued as COSV100868445; called by muse, mutect2, varscan2
- PAQR5 | c.447T>G p.H149Q | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.363); catalogued as COSV100575584; called by muse, mutect2, varscan2
- PCDH9 | c.2500G>C p.V834L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as COSV100122556, COSV60525121; called by muse, mutect2, varscan2
- PCDHB9 | c.1248G>C p.E416D | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs782099946; called by muse, mutect2
- PDE11A | c.1689G>A p.M563I | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as COSV99614100; called by muse, mutect2, varscan2
- PEG10 | c.149C>A p.P50H (on ENST00000482108 / NM_001040152.2; = p.P84H on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV101509940; called by muse, mutect2, varscan2
- PHKA2 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV101177331; called by muse, mutect2, varscan2
- PKHD1L1 | c.8273C>A p.S2758Y | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV101006634, COSV65738685; called by muse, mutect2, varscan2
- PLAC1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 49/172 reads (28%) | catalogued as COSV100821619; called by muse, mutect2, varscan2
- PLCB2 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 118/185 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376425228; called by muse, mutect2, varscan2
- PLCD4 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.373); catalogued as COSV101335825; called by muse, mutect2, varscan2
- PLEKHG5 | c.2559C>A p.D853E (on ENST00000400915 / NM_001042663.3; = p.D816E on NM_020631.6) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100557053; called by muse, varscan2
- PLXNA3 | c.2300G>T p.W767L | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100860176; called by muse, mutect2, varscan2
- POM121 | c.3268G>T p.G1090C (on ENST00000434423; = p.G825C on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99988981; called by muse, mutect2, varscan2
- POM121L12 | c.637C>G p.R213G | Missense Mutation (SNP) | VAF 28/472 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs778713354, COSV101374810; called by muse, mutect2
- PPP2R1A | c.1367A>G p.Y456C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1031829242, COSV100436410; called by muse, mutect2, varscan2
- PPP2R2B | c.374A>T p.K125M (on ENST00000394409; = p.K191M on NM_181674.2) | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV100355813; called by muse, mutect2, varscan2
- PPP2R3B | c.1367A>G p.Q456R | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101180765; called by muse, mutect2, varscan2
- PRKCQ | c.570C>A p.C190* | Nonsense Mutation (SNP) | VAF 106/223 reads (48%) | catalogued as COSV99577559; called by muse, mutect2, varscan2
- PRR23B | c.209G>C p.R70P | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs760663817, COSV100272183; called by muse, mutect2, varscan2
- PTH | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 40/68 reads (59%) | catalogued as COSV56378328, COSV99961719; called by muse, mutect2, varscan2
- PTPN14 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 62/171 reads (36%) | catalogued as COSV100872853; called by muse, mutect2, varscan2
- PXDNL | c.3893G>T p.C1298F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62492223; called by muse, mutect2, varscan2
- PXDNL | c.775G>C p.G259R | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100685416; called by muse, mutect2, varscan2
- RAD9B | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.96); catalogued as COSV100799409; called by muse, mutect2, varscan2
- RAMP3 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs370868982; called by muse, mutect2, varscan2
- RASA1 | c.3085A>G p.I1029V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377550978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REEP2 | c.595A>G p.N199D | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1561807825, COSV99649710; called by muse, mutect2, varscan2
- RGMB | c.817G>C p.A273P (on ENST00000513185 / NM_001366508.1; = p.A314P on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100374987, COSV57567093; called by muse, mutect2, varscan2
- RNF19A | c.1297G>A p.V433M | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1052516178, COSV100347999; called by muse, mutect2, varscan2
- ROCK1 | c.375G>T p.R125S | Missense Mutation (SNP) | VAF 81/105 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101296568; called by muse, mutect2, varscan2
- RTL3 | c.1357C>A p.H453N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100330003; called by muse, mutect2, varscan2
- RTN1 | c.1463C>A p.P488H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99956488; called by muse, mutect2
- RTP1 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1209861869, COSV100398757, COSV56618201; called by muse, mutect2, varscan2
- SCN11A | c.4886T>A p.V1629E | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV100182154; called by muse, mutect2, varscan2
- SDK1 | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761765581, COSV67360185; called by muse, mutect2, varscan2
- SEC14L3 | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99307286; called by muse, mutect2, varscan2
- SEMA3D | c.2240G>T p.G747V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV52394959; called by muse, mutect2, varscan2
- SEMA5B | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV99532848; called by muse, mutect2, varscan2
- SEPTIN6 | c.902G>C p.C301S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.998); catalogued as COSV100595727; called by muse, mutect2, varscan2
- SESN2 | c.281G>C p.W94S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV99456013; called by muse, mutect2, varscan2
- SESN3 | c.575A>G p.H192R | Missense Mutation (SNP) | VAF 88/128 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99565877; called by muse, mutect2, varscan2
- SH3RF2 | c.1054G>C p.G352R | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.641); catalogued as COSV100767937; called by muse, mutect2, varscan2
- SHROOM4 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99174148; called by muse, mutect2, varscan2
- SI | c.4118G>A p.W1373* | Nonsense Mutation (SNP) | VAF 25/84 reads (30%) | catalogued as COSV100014243, COSV100016676; called by muse, mutect2, varscan2
- SIGLEC12 | c.1529C>A p.A510E (on ENST00000291707 / NM_053003.4; = p.A392E on NM_033329.2) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV99389527; called by muse, mutect2, varscan2
- SLC12A1 | c.1181T>C p.I394T | Missense Mutation (SNP) | VAF 69/116 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100372488; called by muse, mutect2, varscan2
- SLC18A3 | c.802G>C p.A268P | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.69); catalogued as COSV100340676; called by muse, mutect2, varscan2
- SLC25A53 | c.40C>A p.H14N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100656098; called by muse, mutect2, varscan2
- SLC2A13 | c.1051A>T p.I351F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55124714, COSV99786892; called by muse, mutect2, varscan2
- SLC30A9 | c.46T>G p.S16A | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV100048431; called by muse, mutect2, varscan2
- SLC32A1 | c.953C>A p.T318K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99462550; called by muse, mutect2, varscan2
- SLC44A5 | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV100901847; called by muse, mutect2, varscan2
- SLC5A4 | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs780445431, COSV99832085; called by muse, mutect2, varscan2
- SLCO1B3 | c.1717G>C p.G573R | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99682016; called by muse, mutect2, varscan2
- SMG7 | c.2911_2912insT p.A971Vfs*12 | Frame Shift Ins (INS) | VAF 34/125 reads (27%) | catalogued as COSV100750497; called by mutect2, pindel, varscan2
- SPATA31E1 | c.527C>A p.P176Q | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100350844, COSV57789888; called by muse, mutect2, varscan2
- SPOP | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100753518; called by muse, mutect2, varscan2
- SRPK2 | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100624232; called by muse, mutect2, varscan2
- ST6GAL1 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 24/101 reads (24%) | PolyPhen benign (0.103); catalogued as rs368118201; called by muse, mutect2, varscan2
- SVEP1 | c.626C>A p.A209E | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV100238772; called by muse, mutect2, varscan2
- SYNE1 | c.22639G>A p.V7547M (on ENST00000367255 / NM_182961.4; = p.V7476M on NM_033071.3) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99574501; called by muse, mutect2, varscan2
- SYNGR4 | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV100785134, COSV61225069; called by muse, mutect2, varscan2
- TACR1 | c.1045T>G p.Y349D | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV100538096, COSV104397629; called by muse, mutect2, varscan2
- TAFA5 | c.170C>T p.P57L (on ENST00000402357 / NM_001082967.3; = p.P50L on NM_015381.7) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100386557; called by muse, mutect2, varscan2
- TAS2R1 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as rs760726632, COSV101225755, COSV101225832; called by muse, mutect2, varscan2
- TAS2R30 | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.015); catalogued as COSV101115338; called by muse, mutect2, varscan2
- TAS2R46 | c.459A>G p.I153M | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as rs1300081825, COSV101115337; called by muse, mutect2, varscan2
- TDRKH | c.830A>G p.D277G | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100918011; called by muse, mutect2, varscan2
- TG | c.4616G>T p.G1539V | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV99602484; called by muse, mutect2, varscan2
- TG | c.6544C>A p.H2182N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.191); catalogued as COSV99602487; called by muse, mutect2, varscan2
- TMEM171 | c.419G>A p.W140* | Nonsense Mutation (SNP) | VAF 55/142 reads (39%) | catalogued as rs369978015; called by muse, mutect2, varscan2
- TMEM185A | c.943C>G p.P315A | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1322574492; called by muse, mutect2, varscan2
- TMEM199 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV99134848; called by muse, mutect2, varscan2
- TMEM200A | c.1111C>G p.Q371E | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99759760; called by muse, mutect2, varscan2
- TMEM63C | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV100029648; called by muse, mutect2, varscan2
- TNXB | c.9980G>T p.W3327L (on ENST00000647633; = p.W3080L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100926515; called by muse, mutect2, varscan2
- TOX2 | c.442C>T p.Q148* (on ENST00000358131 / NM_001098798.2; = p.Q97* on NM_032883.3) | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | catalogued as COSV100364433; called by muse, mutect2, varscan2
- TRIM60 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100594084; called by muse, mutect2, varscan2
- TRIP11 | c.36G>T p.L12F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as COSV99971031; called by muse, mutect2, varscan2
- TRPC5 | c.1879T>C p.S627P | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53286461; called by muse, mutect2, varscan2
- TRPV5 | c.201C>G p.D67E | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV99520866; called by muse, mutect2, varscan2
- TSPEAR | c.1781T>A p.V594E | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100554964; called by muse, mutect2, varscan2
- TSPYL2 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs782124596, COSV64921238; called by mutect2, varscan2
- TTN | c.94754C>A p.P31585H (on ENST00000591111; = p.P24161H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | PolyPhen probably damaging (1); catalogued as COSV100624023; called by muse, mutect2, varscan2
- TTN | c.69416G>T p.R23139L (on ENST00000591111; = p.R15715L on NM_003319.4) | Missense Mutation (SNP) | VAF 51/142 reads (36%) | PolyPhen possibly damaging (0.671); catalogued as COSV100624028, COSV60003059; called by muse, mutect2, varscan2
- TUBE1 | c.1354C>A p.Q452K | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100037151; called by muse, mutect2, varscan2
- UNC5A | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 38/126 reads (30%) | catalogued as COSV99994962; called by muse, mutect2, varscan2
- USH2A | c.2993G>C p.R998T | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.356); catalogued as CS103948, COSV100239372, COSV100239914; called by muse, mutect2, varscan2
- USP6 | c.4075G>A p.D1359N | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.772); catalogued as rs781210816, COSV100003691; called by muse, mutect2, varscan2
- VCAN | c.1609A>T p.S537C | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV99426845; called by muse, mutect2, varscan2
- VCAN | c.2459C>A p.P820H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV54110090, COSV99426847; called by muse, mutect2, varscan2
- VSTM2A | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 28/694 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.38); catalogued as COSV100173276; called by muse, mutect2
- WEE2 | c.1052T>C p.M351T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101187678; called by muse, mutect2, varscan2
- WNK3 | c.1663A>T p.K555* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV100671918; called by muse, mutect2, varscan2
- WNK3 | c.1100C>G p.P367R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100671920; called by muse, mutect2, varscan2
- WNT2B | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV99861898; called by muse, mutect2, varscan2
- XIAP | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100848926; called by muse, mutect2, varscan2
- XKR6 | c.1306G>T p.G436W | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344144428, COSV100441011; called by muse, mutect2, varscan2
- XKR7 | c.1178T>A p.L393Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV101629289; called by muse, mutect2, varscan2
- ZC3H6 | c.1939A>T p.S647C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100674792; called by muse, mutect2, varscan2
- ZFHX4 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.994); catalogued as COSV99261781, COSV99266145; called by muse, mutect2, varscan2
- ZIC1 | c.1044C>A p.D348E | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as COSV99292243; called by muse, mutect2, varscan2
- ZNF17 | c.415A>T p.S139C | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.57); catalogued as COSV100300143, COSV56922670; called by muse, mutect2, varscan2
- ZNF419 | c.1061A>G p.H354R | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99692484; called by muse, mutect2, varscan2
- ZNF479 | c.157G>T p.V53F | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV100482955; called by muse, mutect2, varscan2
- ZNF546 | c.2275C>A p.R759S | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV100713526; called by muse, mutect2, varscan2
- ZNF582 | c.1305C>A p.C435* | Nonsense Mutation (SNP) | VAF 36/111 reads (32%) | catalogued as COSV100018863; called by muse, mutect2, varscan2
- ZNF598 | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs147389225; called by muse, mutect2, varscan2
- ZNF804A | c.2418C>A p.C806* | Nonsense Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as COSV100169469; called by muse, mutect2, varscan2
- ZSCAN4 | c.890C>T p.T297I | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV99990195; called by muse, mutect2, varscan2
- ACOXL | c.1407del p.W469* (on ENST00000389811 / NM_001371254.1; = p.W439* on NM_001142807.4) | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | called by mutect2, pindel, varscan2
- ADAM18 | c.1309dup p.C437Lfs*6 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- ATRNL1 | c.554del p.G185Afs*15 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | called by mutect2, pindel, varscan2
- C1orf116 | c.799_813delinsTT p.A267Lfs*20 | Frame Shift Del (DEL) | VAF 42/124 reads (34%) | called by pindel, varscan2*
- CLTCL1 | c.3984del p.K1328Nfs*22 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- COL11A1 | c.2243del p.G748Vfs*17 | Frame Shift Del (DEL) | VAF 34/78 reads (44%) | called by mutect2, pindel, varscan2
- EWSR1 | c.354dup p.G119Wfs*29 | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.521del p.G174Afs*36 | Frame Shift Del (DEL) | VAF 40/342 reads (12%) | called by pindel, varscan2
- FRG2C | c.260C>G p.P87R | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HNRNPCL1 | c.472del p.S158Vfs*18 | Frame Shift Del (DEL) | VAF 70/223 reads (31%) | called by mutect2, pindel, varscan2
- IGKV1D-42 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- KCNH2 | c.1598T>A p.V533E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KIAA1755 | c.2255del p.P752Lfs*11 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- MLLT6 | c.3271G>T p.E1091* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- MME | c.1285del p.E429Kfs*15 | Frame Shift Del (DEL) | VAF 40/200 reads (20%) | called by pindel, varscan2
- NOTCH1 | c.3504del p.C1169Afs*10 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- PGM2 | c.1045del p.A349Pfs*41 | Frame Shift Del (DEL) | VAF 36/151 reads (24%) | called by mutect2, pindel, varscan2
- SCN11A | c.5268dup p.G1757Rfs*2 | Frame Shift Ins (INS) | VAF 36/84 reads (43%) | called by mutect2, pindel, varscan2
- SLC30A9 | c.1277del p.G426Vfs*9 | Frame Shift Del (DEL) | VAF 52/180 reads (29%) | called by mutect2, pindel, varscan2
- ST8SIA6 | c.481dup p.E161Gfs*5 | Frame Shift Ins (INS) | VAF 28/111 reads (25%) | called by mutect2, pindel, varscan2
- TAGLN3 | c.14del p.G5Afs*6 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | called by mutect2, pindel, varscan2
- TRAV12-3 | c.37T>A p.W13R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- TRIM58 | c.613del p.E205Rfs*25 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- ZNF318 | c.5265_5284del p.N1756Rfs*4 | Frame Shift Del (DEL) | VAF 21/112 reads (19%) | called by mutect2, pindel, varscan2
- ALOX5 | c.231G>A p.L77= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV65551091; called by muse, mutect2, varscan2
- ANKRD11 | c.5832C>G p.T1944= | Silent (SNP) | VAF 58/84 reads (69%) | catalogued as COSV99970257; called by muse, mutect2, varscan2
- APBA2 | c.1419C>A p.R473= | Silent (SNP) | VAF 32/42 reads (76%) | catalogued as COSV101258198; called by muse, mutect2, varscan2
- ASB5 | c.6G>T p.S2= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs559244303, COSV99641979; called by muse, mutect2, varscan2
- CACNA1B | c.4458G>A p.V1486= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99498946; called by muse, mutect2, varscan2
- CATSPER2 | c.39C>A p.P13= | Silent (SNP) | VAF 208/334 reads (62%) | catalogued as COSV100390938; called by muse, mutect2, varscan2
- CCDC70 | c.432C>A p.A144= | Silent (SNP) | VAF 56/92 reads (61%) | catalogued as COSV99665417; called by muse, mutect2, varscan2
- CD163L1 | c.627T>C p.N209= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100550530; called by muse, mutect2, varscan2
- CDH3 | c.1392A>G p.A464= | Silent (SNP) | VAF 123/172 reads (72%) | catalogued as COSV99868929; called by muse, mutect2, varscan2
- CHIA | c.1107C>T p.G369= (on ENST00000343320; = p.G261= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV58477067; called by muse, mutect2, varscan2
- CILP | c.2886G>C p.G962= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV99973793; called by muse, mutect2, varscan2
- CNOT1 | c.5943T>C p.R1981= | Silent (SNP) | VAF 50/78 reads (64%) | catalogued as COSV99800904; called by muse, mutect2, varscan2
- CROT | c.609T>C p.F203= | Silent (SNP) | VAF 58/180 reads (32%) | catalogued as COSV100519636; called by muse, mutect2, varscan2
- CSAG2 | c.351C>A p.I117= | Silent (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- CSMD1 | c.1917C>T p.L639= (on ENST00000520002; = p.L638= on NM_033225.6) | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs748994048, COSV100154401, COSV59330600; called by muse, mutect2, varscan2
- CSMD2 | c.3774G>A p.R1258= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV53928519; called by muse, mutect2, varscan2
- CYP26A1 | c.633G>A p.V211= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as COSV99814889; called by muse, mutect2, varscan2
- CYTH4 | c.180G>A p.Q60= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99958106; called by muse, mutect2, varscan2
- DAAM2 | c.3195G>T p.R1065= (on ENST00000274867 / NM_001201427.2; = p.R1064= on NM_015345.3) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV51389046; called by muse, mutect2, varscan2
- DDX51 | c.654C>A p.I218= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV100223164; called by muse, mutect2, varscan2
- DNAH10 | c.6018C>A p.P2006= (on ENST00000409039; = p.P1945= on NM_207437.3) | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs201453347, COSV101292489; called by muse, mutect2, varscan2
- DPP4 | c.129C>T p.Y43= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100858998; called by muse, mutect2, varscan2
- DPP6 | c.297A>G p.A99= (on ENST00000377770 / NM_001364500.2; = p.A37= on NM_001936.5) | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV100127298; called by muse, mutect2, varscan2
- EFHC2 | c.1668A>G p.E556= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100638017; called by muse, mutect2, varscan2
- EMC2 | c.129A>G p.E43= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV99624431; called by muse, mutect2, varscan2
- ENPP6 | c.997C>A p.R333= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV99699060; called by muse, mutect2, varscan2
- ESX1 | c.441G>T p.T147= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as COSV101006491; called by muse, mutect2, varscan2
- EXOSC1 | c.153A>T p.P51= | Silent (SNP) | VAF 58/179 reads (32%) | catalogued as COSV100620603; called by muse, mutect2, varscan2
- FAM135B | c.3610T>C p.L1204= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99426313; called by muse, mutect2, varscan2
- FAM47C | c.27G>C p.R9= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100792328, COSV100792874, COSV63727200; called by muse, mutect2, varscan2
- FAM47C | c.600G>T p.P200= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100792875; called by muse, mutect2, varscan2
- FAT4 | c.2169T>G p.T723= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV67884407; called by muse, mutect2, varscan2
- FBXO38 | c.3357C>T p.F1119= (on ENST00000340253 / NM_205836.3; = p.F1044= on NM_030793.5) | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs577469242, COSV99693813; ClinVar: benign; called by muse, mutect2, varscan2
- FCRL5 | c.828C>A p.S276= | Silent (SNP) | VAF 96/283 reads (34%) | catalogued as COSV62519549; called by muse, mutect2, varscan2
- GAL3ST3 | c.754C>A p.R252= | Silent (SNP) | VAF 35/60 reads (58%) | catalogued as rs766591146, COSV100360960, COSV61748650; called by muse, mutect2, varscan2
- GALNT13 | c.567A>T p.I189= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV101223954; called by muse, mutect2, varscan2
- GIGYF2 | c.1917T>C p.V639= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV101004574; called by muse, mutect2, varscan2
- GIMAP8 | c.27C>T p.S9= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs370191374; called by muse, mutect2, varscan2
- GPLD1 | c.720G>T p.V240= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100015504; called by muse, mutect2, varscan2
- H1-5 | c.510G>T p.V170= | Silent (SNP) | VAF 62/202 reads (31%) | catalogued as COSV100138026; called by muse, mutect2, varscan2
- HECTD4 | c.12981G>A p.E4327= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV101108229; called by muse, mutect2, varscan2
- HTR2C | c.162C>T p.N54= | Silent (SNP) | VAF 57/158 reads (36%) | catalogued as COSV99350452; called by muse, mutect2, varscan2
- IL13RA1 | c.246T>A p.T82= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV100861742; called by muse, mutect2, varscan2
- IPO5 | c.12C>A p.A4= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1263387229, COSV99847558; called by muse, mutect2, varscan2
- IRF1 | c.912C>G p.T304= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99810660; called by muse, mutect2, varscan2
- ITGA11 | c.1632C>G p.S544= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100242026; called by muse, mutect2, varscan2
- ITGA4 | c.1647G>A p.Q549= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV99276684; called by muse, mutect2, varscan2
- KCNH6 | c.1227G>A p.A409= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as rs764333218, COSV59006744; called by muse, mutect2, varscan2
- KIAA0100 | c.3681C>T p.V1227= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV101197372; called by muse, mutect2, varscan2
- KLHL4 | c.42C>A p.I14= | Silent (SNP) | VAF 58/190 reads (31%) | catalogued as COSV100910077, COSV64146385; called by muse, mutect2, varscan2
- KNTC1 | c.4833A>G p.E1611= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs760590719, COSV100338656; called by muse, mutect2, varscan2
- LILRA2 | c.1377C>A p.V459= (on ENST00000391738 / NM_001130917.3; = p.V442= on NM_006866.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV52196746, COSV99253778; called by muse, mutect2, varscan2
- LYRM9 | c.33G>T p.R11= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100991868; called by muse, mutect2, varscan2
- MAGEA11 | c.240C>A p.T80= | Silent (SNP) | VAF 82/202 reads (41%) | catalogued as COSV60758847; called by muse, mutect2, varscan2
- MAGEB10 | c.612G>C p.L204= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100775350; called by muse, mutect2, varscan2
- MED7 | c.231A>G p.E77= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV99644292; called by muse, mutect2, varscan2
- MLN | c.198G>A p.A66= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs377738233; called by muse, mutect2, varscan2
- MRGPRD | c.703C>T p.L235= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100483070; called by muse, mutect2, varscan2
- MUC16 | c.42510C>A p.T14170= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV101110017; called by muse, mutect2, varscan2
- MYH8 | c.2823C>A p.A941= | Silent (SNP) | VAF 61/143 reads (43%) | catalogued as COSV101238613; called by muse, mutect2, varscan2
- NAP1L3 | c.261G>C p.A87= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100220578, COSV100220708; called by muse, mutect2, varscan2
- NCL | c.1869C>T p.A623= | Silent (SNP) | VAF 73/225 reads (32%) | catalogued as COSV100502438; called by muse, mutect2, varscan2
- NKAIN2 | c.501T>C p.Y167= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs747121176, COSV100866179; called by muse, mutect2, varscan2
- OLFML2B | c.1737C>A p.R579= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV54194361; called by muse, mutect2, varscan2
- OR5D18 | c.553C>T p.L185= | Silent (SNP) | VAF 99/147 reads (67%) | catalogued as COSV100450820; called by muse, mutect2, varscan2
- OR9A2 | c.852C>T p.F284= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as COSV63306596; called by muse, mutect2, varscan2
- OTUD4 | c.1629A>T p.T543= (on ENST00000447906 / NM_001366057.1; = p.T478= on NM_001102653.1) | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV101486039; called by muse, mutect2, varscan2
- P2RX2 | c.105G>A p.V35= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100267787; called by muse, mutect2, varscan2
- PAPPA2 | c.2706G>A p.V902= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as rs766741186, COSV100866988; called by muse, mutect2, varscan2
- PCDHGA10 | c.1449G>T p.P483= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as COSV99543981; called by muse, mutect2, varscan2
- PHACTR4 | c.1782A>C p.T594= (on ENST00000373839 / NM_001350159.2; = p.T604= on NM_023923.4) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100868487, COSV65784764; called by muse, mutect2, varscan2
- PKHD1 | c.2884T>C p.L962= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100584131; called by muse, mutect2, varscan2
- PNKP | c.126G>T p.T42= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as COSV100465572; called by muse, mutect2, varscan2
- POLD1 | c.1872C>T p.P624= | Silent (SNP) | VAF 60/150 reads (40%) | catalogued as rs200649908, COSV70957808; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPM1G | c.993G>A p.A331= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs149149429; called by mutect2, varscan2
- PPP1R9A | c.840A>G p.P280= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV99196830; called by muse, mutect2, varscan2
- PRKRA | c.183A>T p.I61= | Silent (SNP) | VAF 90/292 reads (31%) | catalogued as COSV100359761; called by muse, mutect2, varscan2
- PTGDS | c.462C>A p.T154= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs1454744827, COSV99812001; called by muse, mutect2, varscan2
- RAB6B | c.261G>T p.T87= | Silent (SNP) | VAF 74/159 reads (47%) | catalogued as COSV99558183; called by muse, mutect2, varscan2
- RBMXL1 | c.156T>A p.A52= | Silent (SNP) | VAF 30/210 reads (14%) | catalogued as COSV99556781; called by muse, mutect2
- SAFB | c.1641A>G p.S547= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs919921260, COSV99413123; called by muse, mutect2, varscan2
- SLC8B1 | c.165G>A p.K55= | Silent (SNP) | VAF 57/202 reads (28%) | catalogued as rs1430990069, COSV99176803; called by muse, mutect2, varscan2
- SLIT1 | c.2257C>A p.R753= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV56594082, COSV99822169; called by muse, mutect2, varscan2
- SP5 | c.939G>T p.L313= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100935342; called by muse, mutect2, varscan2
- SPATA31E1 | c.3762G>A p.K1254= | Silent (SNP) | VAF 29/54 reads (54%) | catalogued as COSV100350847; called by muse, mutect2, varscan2
- STARD13 | c.2649G>A p.V883= (on ENST00000336934 / NM_001243476.3; = p.V765= on NM_052851.3) | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs1233512103, COSV99716238; called by muse, mutect2, varscan2
- SYCP2L | c.1641A>T p.P547= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV99305642; called by muse, mutect2, varscan2
- TAB3 | c.642A>G p.Q214= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs779868679, COSV99916615; called by muse, mutect2, varscan2
- TECPR2 | c.2382C>T p.L794= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs369859838; called by muse, mutect2, varscan2
- TGIF2LX | c.177C>A p.A59= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs1569307838, COSV99383299, COSV99383406; called by muse, mutect2, varscan2
- TMC7 | c.1401A>G p.T467= | Silent (SNP) | VAF 55/146 reads (38%) | catalogued as COSV100432731; called by muse, mutect2, varscan2
- TPO | c.846G>A p.A282= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs1409799490, COSV100221784; called by muse, mutect2, varscan2
- TRAV3 | c.150T>A p.P50= | Silent (SNP) | VAF 33/98 reads (34%) | called by muse, mutect2, varscan2
- TREX2 | c.144C>A p.P48= (on ENST00000334497; = p.P5= on NM_080701.3) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100444258; called by muse, mutect2, varscan2
- TTLL7 | c.819C>T p.S273= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV99552867; called by muse, mutect2, varscan2
- TTN | c.61080C>A p.P20360= (on ENST00000591111; = p.P12936= on NM_003319.4) | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100624031; called by muse, mutect2, varscan2
- UGT1A8 | c.231C>T p.Y77= | Silent (SNP) | VAF 68/187 reads (36%) | catalogued as COSV100990687; called by muse, mutect2, varscan2
- ZC3H11A | c.2067C>T p.S689= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV100142602; called by muse, mutect2, varscan2
- ZIC1 | c.459C>T p.H153= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99292241; called by muse, mutect2
- ZNF492 | c.51G>A p.K17= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as COSV101514039; called by muse, mutect2, varscan2
- ZNF630 | c.1719T>C p.C573= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs781924718, COSV99332520; called by muse, mutect2, varscan2
- ZP4 | c.786T>C p.T262= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs566640263, COSV100850750; called by muse, mutect2, varscan2
- ZXDB | c.402G>T p.A134= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV66492516; called by muse, varscan2
- C7orf66 | n.255C>T | RNA (SNP) | VAF 42/151 reads (28%) | called by muse, mutect2, varscan2
- CLCA3P | n.584C>A | RNA (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
- DCHS2 | n.3714G>A | RNA (SNP) | VAF 14/38 reads (37%) | catalogued as rs954880214, COSV100602351; called by muse, mutect2, varscan2
- DUSP13 | c.*768A>G | 3'UTR (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100403704; called by muse, mutect2, varscan2
- MIR154 | n.25G>T | RNA (SNP) | VAF 103/354 reads (29%) | called by muse, mutect2, varscan2
- NEBL | c.164+46421A>T | Intron (SNP) | VAF 50/98 reads (51%) | catalogued as COSV101008822; called by muse, mutect2, varscan2
- OPRM1 | c.1164+1884C>G | Intron (SNP) | VAF 75/242 reads (31%) | catalogued as COSV100002117; called by muse, mutect2, varscan2
- OR2W5 | n.1101A>G | RNA (SNP) | VAF 64/136 reads (47%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791659 TGTACCCATTTTGCCACCTTCCTCTGTGGT>GTACCCATTTTGCCACCTTCCTCTGTGGTC | 3'Flank (ONP) | VAF 17/74 reads (23%) | called by mutect2*, pindel, varscan2*
- SLCO1B3-SLCO1B7 | c.1866-15092del | Intron (DEL) | VAF 30/127 reads (24%) | catalogued as COSV67441865; called by mutect2, pindel, varscan2
- XIST | n.9156A>T | RNA (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
